FM case AD17238 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/9581e1f0-4ada-4e07-84f7-cbddd699c2cb

Female, 54.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the head, face or neck; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
